Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84M, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84M-01A (Primary Tumor).

[page 1 of 2]
Patient Results

Neurological Pathology results performed since

Results

At least Final Result

Final

Page 2

PATIENT

SEX

DOB

DOCTOR

DOC. ADDRESS

D.O.B.

ADDRESS

COLL. DATE

DATE RECEIVED

ACC. NO.

WARD

LAB. NO.

CONSULTANT

HISTOPATHOLOGY REPORT

SPECIMEN:

Right frontal tumour.

CLINICAL:

?Low grade glioma, incidental on trauma scan.

From Imaging: Hyperintense mass in the right inferior frontal gyrus measuring up to 4cm. Calcification noted with the mass and mild enhancement following contrast (MRI, study date). No notable changes on the surgical planning scan on

MACROSCOPIC:

A portion of brain, grey/white tissue 30 x 20 x 10mm.

INTRA-OPERATIVE ASSESSMENT - FROZEN SECTION/IMPRINT CYTOLOGY:

Glial series tumour. No definite features of high grade.

result phoned to

BLOCK KEY:

1:frozen piece, 2-10:remainder of tissue.

MICROSCOPIC:

The entire specimen has been submitted for histological examination, and the permanent sections confirm intra-operative assessment findings of a glial series tumour. The tumour is composed of sheet-like proliferation of small round, uniform cells with central nuclei with a perinuclear halo. In areas, the cellular density is increased and the tumour cells assume an epithelioid appearance with enlarged nuclei, open chromatin and conspicuous nucleoli. The tumour diffusely infiltrates the cerebral parenchyma and aggregates beneath the pia mater. There is a delicate vasculature within the tumour however no microvascular endothelial proliferation is seen. Areas aggregates of calcification as well as microcyst formation are observed. Minigemistocytes are conspicuous in areas and focally, the nuclei assume an angulated profile. Mitotic activity and apoptotic bodies are increased within areas of increased cellular density, and a mitotic count is numbered at 9 per 10 high power fields (field diameter 0.55mm). Proliferation index is estimated at 10% by MIB1 staining. There is no definite necrosis. Staining with p53 is weak however stronger reactivity is observed in some cells. GFAP highlights the minigemistocytes.

Representative formalin fixed paraffin embedded tissue sections were submitted for FISH [fluorescence in situ hybridization] studies to assess 1p, 19q and EGFR. The FISH studies were performed in the

The

100-3
Oligodendroglioma, grade III 945/13
Site: Right superior frontal lobe C71.0
R: Brain, frontal lobe C71.0
9/10/13

Received in

End of Report

Printed from

Page 1 of 2

[page 2 of 2]
results
confirmed since [redacted]
[redacted]
[redacted]

results of the studies (which have been reported separately) demonstrated evidence of both 1p and 19q deletions. EGFR amplification was not detected.

CONCLUSION:
Right frontal tumour: Anaplastic oligodendroglioma, WHO grade III, 1p 19q co-deleted by FISH.

REGISTRAR:
PATHOLOGIST:

DATED:
ELECTRONICALLY VALIDATED:

Source: NCI Genomic Data Commons file 0614dd32-127d-4fd8-8323-78b7cd69ffd9 (TCGA-TM-A84M.A9063552-B6AE-4CD9-9A0C-BF7BA476411C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).